Somatic mutation profile of tumor specimen TCGA-EB-A3XF-01A (aliquot TCGA-EB-A3XF-01A-31D-A23B-08) from TCGA case TCGA-EB-A3XF, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 57.2 years (20,910 days).
Specimen TCGA-EB-A3XF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c16be72d-0760-41dc-b828-dbe5d0b46ac3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A3XF-10A (Blood Derived Normal), aliquot TCGA-EB-A3XF-10A-01D-A23B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1b47436-bc2a-48b3-8104-7e8850b14a38

The open-access MAF lists 466 somatic variants for this specimen: 303 protein-altering or splice-affecting, 154 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 268, Silent 154, Nonsense Mutation 24, Splice Region 4, Intron 4, Splice Site 4, RNA 2, 3'UTR 2, Frame Shift Del 2, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs1057519732, COSV61068297; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.7357G>A p.E2453K (on ENST00000272895 / NM_173076.3; = p.E2135K on NM_015657.3) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55948531; called by muse, mutect2, varscan2
- ABCA12 | c.2881C>T p.P961S (on ENST00000272895 / NM_173076.3; = p.P643S on NM_015657.3) | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs935665803, COSV55968924, COSV99791111; called by muse, mutect2, varscan2
- ABCB4 | c.2087C>T p.S696F | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99710890; called by muse, mutect2, varscan2
- ABCC6 | c.1991C>T p.P664L | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV99229238; called by muse, mutect2, varscan2
- AC126283.2 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV101144586; called by muse, mutect2, varscan2
- ADAM18 | c.1768G>A p.D590N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs1321734632, COSV55846199, COSV99695915; called by muse, mutect2, varscan2
- ADAMTS16 | c.2792G>A p.W931* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV99942123; called by mutect2, varscan2
- ADAMTS20 | c.5556T>A p.N1852K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101239882; called by muse, mutect2
- ADCY4 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.264); catalogued as rs773348354, COSV100156718; called by muse, mutect2, varscan2
- ADGRL2 | c.2503G>A p.E835K (on ENST00000370717 / NM_001366005.1; = p.E822K on NM_012302.4) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as rs1324770310, COSV54660901; called by muse, mutect2, varscan2
- ADGRV1 | c.12161C>T p.S4054L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV101316244; called by muse, mutect2, varscan2
- AGFG1 | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59510303; called by muse, mutect2, varscan2
- AKR1C1 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV101080524; called by muse, mutect2, varscan2
- ALMS1 | c.12332G>A p.S4111N | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as COSV100043177; called by muse, mutect2, varscan2
- ALPG | c.1342G>A p.G448R | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV54967137; called by muse, mutect2, varscan2
- AMPD1 | c.831G>A p.M277I | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as COSV62418627; called by muse, mutect2, varscan2
- AMY1C | c.879G>A p.K293= | Splice Region (SNP) | VAF 30/326 reads (9%) | catalogued as COSV64407220; called by muse, mutect2
- ANGPT1 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs868669098, COSV52433932; called by muse, mutect2, varscan2
- ANK3 | c.12978G>A p.M4326I (on ENST00000280772 / NM_001320874.2; = p.M950I on NM_001149.3) | Missense Mutation (SNP) | VAF 79/131 reads (60%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.241); catalogued as COSV99781269; called by muse, mutect2, varscan2
- ANKRD45 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV100322515; called by muse, mutect2, varscan2
- ANO4 | c.169G>A p.D57N (on ENST00000392977 / NM_001286615.2; = p.D22N on NM_178826.4) | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.956); catalogued as rs373885901; called by muse, mutect2, varscan2
- AOC1 | c.2030C>T p.P677L | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100710876; called by muse, mutect2, varscan2
- AOX1 | c.2290G>A p.G764R | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.411); catalogued as rs756119874, COSV101022164; called by muse, mutect2, varscan2
- AP1S3 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100525354; called by muse, mutect2, varscan2
- ARAP2 | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 28/79 reads (35%) | catalogued as COSV58281921; called by muse, mutect2, varscan2
- ARHGAP18 | c.1839-1G>T p.X613_splice | Splice Site (SNP) | VAF 4/23 reads (17%) | catalogued as COSV100936017; called by muse, mutect2, varscan2
- ART5 | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs748533200, COSV63364036; called by muse, mutect2, varscan2
- ASCC3 | c.5149C>T p.L1717F | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100976913, COSV64975116; called by muse, mutect2, varscan2
- ASIC5 | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV72232691, COSV72233239; called by muse, mutect2
- ATF7 | c.497C>T p.S166F (on ENST00000548446 / NM_001366555.2; = p.S155F on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100129642; called by muse, mutect2, varscan2
- ATP13A5 | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1340327629, COSV60865060; called by muse, mutect2, varscan2
- ATP13A5 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV100665450; called by muse, mutect2, varscan2
- ATP1A2 | c.1106C>T p.S369F | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100768026; called by muse, mutect2
- ATP6V0A4 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.207); catalogued as COSV100023367; called by muse, mutect2, varscan2
- ATP6V1B2 | c.604-2A>C p.X202_splice | Splice Site (SNP) | VAF 14/52 reads (27%) | catalogued as COSV99369529, COSV99369650; called by muse, mutect2, varscan2
- B4GALNT2 | c.1210C>T p.L404F | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.105); catalogued as COSV100302667; called by muse, mutect2, varscan2
- BCLAF1 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.306); catalogued as COSV62140394; called by muse, mutect2, varscan2
- BIRC3 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.786); catalogued as COSV54817799; called by muse, mutect2, varscan2
- BMP3 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99261876; called by muse, mutect2, varscan2
- BTC | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.977); catalogued as rs140634211; called by muse, mutect2, varscan2
- C15orf39 | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV100641412; called by muse, mutect2, varscan2
- C1S | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100196699; called by muse, mutect2, varscan2
- C8orf34 | c.635G>A p.W212* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100447215; called by muse, mutect2, varscan2
- C9 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs368001255, COSV99661547; called by muse, mutect2, varscan2
- CAD | c.2812C>T p.L938F | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV53024726; called by muse, mutect2, varscan2
- CAPN13 | c.1940A>G p.N647S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as rs762927415, COSV99700611; called by muse, mutect2, varscan2
- CASR | c.1480G>A p.G494R (on ENST00000490131; = p.G571R on NM_000388.4) | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99949260; called by muse, mutect2, varscan2
- CBFA2T2 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1307511590, COSV100656451; called by muse, mutect2, varscan2
- CCDC102A | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 11/65 reads (17%) | catalogued as COSV99265158; called by muse, mutect2, varscan2
- CCDC146 | c.1176G>A p.M392I | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99592929; called by muse, mutect2, varscan2
- CCDC185 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV100838818; called by muse, mutect2, varscan2
- CDH8 | c.1570G>A p.D524N | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.111); catalogued as rs1264566952, COSV100183252, COSV54903538; called by muse, mutect2, varscan2
- CDHR1 | c.1399G>A p.D467N | Missense Mutation (SNP) | VAF 55/89 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60562636; called by muse, mutect2, varscan2
- CDS1 | c.422G>A p.W141* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as COSV99880922; called by muse, mutect2, varscan2
- CFAP92 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs1205336955, COSV99414835; called by muse, mutect2, varscan2
- CHAMP1 | c.1870C>T p.Q624* | Nonsense Mutation (SNP) | VAF 29/87 reads (33%) | catalogued as COSV100778843; called by muse, mutect2, varscan2
- CHL1 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs750674722, COSV56607646; called by muse, mutect2, varscan2
- CHL1 | c.1478C>T p.S493L (on ENST00000397491 / NM_001253387.1; = p.S509L on NM_006614.4) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as rs1309060833, COSV99851769; called by muse, mutect2, varscan2
- CHL1 | c.1579C>T p.P527S (on ENST00000397491 / NM_001253387.1; = p.P543S on NM_006614.4) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.051); catalogued as COSV56597578, COSV56599058; called by muse, mutect2, varscan2
- CLCA4 | c.2123G>A p.G708E | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV100991169; called by muse, mutect2, varscan2
- CLOCK | c.2185A>G p.M729V | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.085); catalogued as COSV100011896; called by muse, mutect2, varscan2
- CLVS2 | c.784G>T p.A262S | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.503); catalogued as COSV99252168; called by muse, mutect2
- CMYA5 | c.11631G>T p.R3877S | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV101405677; called by muse, mutect2, varscan2
- CNGA3 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs149069990; called by muse, mutect2
- CNKSR1 | c.1532C>T p.P511L (on ENST00000374253 / NM_001297647.2; = p.P504L on NM_006314.3) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as COSV100128462; called by muse, mutect2, varscan2
- COL14A1 | c.2518G>A p.E840K | Missense Mutation (SNP) | VAF 53/94 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV52863302; called by muse, mutect2, varscan2
- COL1A2 | c.2119C>T p.P707S | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.197); catalogued as COSV99800455; called by muse, mutect2, varscan2
- COL22A1 | c.3766G>C p.E1256Q | Missense Mutation (SNP) | VAF 81/315 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.784); catalogued as COSV100279599; called by muse, mutect2, varscan2
- COL3A1 | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100483452; called by muse, mutect2, varscan2
- COL4A1 | c.3829C>T p.P1277S | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV101011354; called by muse, mutect2, varscan2
- CPNE2 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as rs1440492702, COSV99321501; called by muse, mutect2, varscan2
- CPSF3 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99433063; called by muse, mutect2, varscan2
- CPSF6 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1223225367, COSV57012354; called by muse, mutect2, varscan2
- CRACD | c.2788C>T p.P930S | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.046); catalogued as COSV99949696, COSV99950181; called by muse, mutect2, varscan2
- CRX | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 110/254 reads (43%) | SIFT tolerated (0.73); PolyPhen benign (0.093); catalogued as COSV99704598; called by muse, mutect2, varscan2
- CSMD1 | c.10370G>A p.G3457E (on ENST00000520002; = p.G3456E on NM_033225.6) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV59301362; called by muse, mutect2, varscan2
- CXCR4 | c.1006G>A p.G336R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as CM045454, COSV54013752, COSV99603271; called by muse, mutect2, varscan2
- CYP26C1 | c.1289C>T p.P430L | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99606071; called by muse, mutect2, varscan2
- CYP2C19 | c.688C>T p.H230Y | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as COSV64908434; called by muse, mutect2, varscan2
- DAGLA | c.2098C>T p.P700S | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.05); catalogued as COSV57199569; called by muse, mutect2, varscan2
- DAPL1 | c.210C>T p.L70= | Splice Region (SNP) | VAF 39/137 reads (28%) | catalogued as COSV59353120; called by muse, mutect2, varscan2
- DDX31 | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs955315949, COSV100140222; called by muse, mutect2, varscan2
- DEK | c.865A>G p.T289A | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); catalogued as COSV99789020; called by muse, mutect2, varscan2
- DENND3 | c.3048G>A p.W1016* | Nonsense Mutation (SNP) | VAF 62/119 reads (52%) | catalogued as COSV99371348; called by muse, varscan2
- DGKD | c.1402T>C p.F468L (on ENST00000264057 / NM_152879.3; = p.F424L on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/114 reads (53%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99897011; called by muse, mutect2, varscan2
- DGKK | c.2574G>A p.M858I | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101053129, COSV101053149; called by muse, mutect2, varscan2
- DLGAP1 | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100232667; called by muse, mutect2, varscan2
- DLGAP3 | c.782G>A p.W261* | Nonsense Mutation (SNP) | VAF 60/167 reads (36%) | catalogued as COSV99332972; called by muse, mutect2, varscan2
- DMBT1 | c.5584G>A p.E1862K (on ENST00000338354 / NM_001377530.1; = p.E1105K on NM_004406.3) | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as rs1045906158, COSV57534249; called by muse, mutect2, varscan2
- DMBX1 | c.964C>A p.Q322K | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV100760842; called by muse, mutect2, varscan2
- DNAH10 | c.3232C>T p.P1078S (on ENST00000409039; = p.P1017S on NM_207437.3) | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101292463; called by muse, mutect2, varscan2
- DNAH2 | c.3496G>A p.D1166N | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs764060648, COSV101209503; called by muse, mutect2, varscan2
- DNAJC14 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.637); catalogued as rs774377537, COSV100423662; called by muse, mutect2, varscan2
- DTL | c.840T>A p.D280E | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100877244; called by muse, mutect2, varscan2
- DYNC1H1 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV100795149; called by muse, mutect2
- EGFLAM | c.407A>G p.Q136R | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV100472735; called by muse, varscan2
- EIF3E | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV99623370; called by muse, mutect2, varscan2
- EML1 | c.1874G>A p.G625E | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV51743272; called by muse, mutect2, varscan2
- ENG | c.193C>T p.H65Y | Missense Mutation (SNP) | VAF 72/124 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100785321; called by muse, mutect2
- ENPP3 | c.952A>G p.T318A | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT tolerated (0.28); PolyPhen benign (0.311); catalogued as COSV100717744; called by muse, mutect2, varscan2
- EPHA6 | c.2252A>G p.E751G (on ENST00000389672 / NM_001080448.3; = p.E143G on NM_173655.4) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101064483; called by muse, mutect2, varscan2
- ERBB4 | c.3007T>A p.F1003I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100726581, COSV61485117; called by muse, mutect2, varscan2
- F10 | c.779T>A p.F260Y | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65020791; called by muse, mutect2, varscan2
- FAM120C | c.3044C>T p.S1015L | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.006); catalogued as CM1513255, COSV100070314; called by muse, mutect2, varscan2
- FAM160A2 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 89/235 reads (38%) | catalogued as rs1564866543, COSV56412559; called by muse, mutect2, varscan2
- FANCM | c.2618G>C p.G873A | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV99951365; called by muse, mutect2
- FBN3 | c.8091G>A p.V2697= | Splice Region (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99495219; called by muse, mutect2
- FBRS | c.1063C>T p.R355C (on ENST00000287468; = p.R875C on NM_001105079.3) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV54918743; called by muse, mutect2, varscan2
- FBXL12 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.4); PolyPhen benign (0.122); catalogued as rs370622099, COSV56113982; called by muse, mutect2, varscan2
- FMO3 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV100882516; called by muse, mutect2, varscan2
- FN1 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100117709; called by muse, mutect2, varscan2
- FSD1 | c.114G>A p.A38= | Splice Region (SNP) | VAF 73/205 reads (36%) | catalogued as rs771967101, COSV55694993, COSV55698017; called by muse, mutect2, varscan2
- FSIP1 | c.1512G>A p.M504I | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV63227319; called by muse, mutect2, varscan2
- FZR1 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100553745; called by muse, mutect2, varscan2
- G6PC2 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99960851; called by muse, mutect2, varscan2
- GALNTL6 | c.1613G>A p.G538E | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101560353; called by muse, mutect2, varscan2
- GAPVD1 | c.3556C>A p.R1186S (on ENST00000394104; = p.R1195S on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52921237, COSV99783512; called by muse, varscan2
- GBA | c.336G>C p.Q112H | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV100516420; called by muse, mutect2, varscan2
- GIPC1 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 50/122 reads (41%) | catalogued as COSV100600132; called by muse, mutect2, varscan2
- GPATCH8 | c.1207A>T p.K403* | Nonsense Mutation (SNP) | VAF 36/98 reads (37%) | catalogued as COSV100132755; called by muse, mutect2, varscan2
- GPR50 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 64/81 reads (79%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as rs765579691, COSV99506419; called by muse, mutect2, varscan2
- GRIK2 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59709996; called by muse, mutect2, varscan2
- GRM8 | c.2512G>A p.V838I | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.522); catalogued as COSV100284724; called by muse, mutect2, varscan2
- GUCY2D | c.1669G>A p.G557R | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1184024632, COSV54694755; called by muse, mutect2, varscan2
- GYPB | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.383); catalogued as rs757106926, COSV51621678; called by muse, mutect2
- HECTD4 | c.7106C>G p.P2369R | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101108094; called by muse, mutect2, varscan2
- HGFAC | c.1920G>A p.W640* | Nonsense Mutation (SNP) | VAF 24/77 reads (31%) | catalogued as COSV101237771; called by muse, mutect2, varscan2
- HSPB3 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100115980; called by muse, mutect2, varscan2
- HTT | c.5125A>G p.T1709A | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100751048, COSV61868704; called by muse, mutect2, varscan2
- IFNL2 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0.029); catalogued as COSV100122110, COSV59594139; called by muse, mutect2, varscan2
- IGBP1P2 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as COSV53617792; called by muse, mutect2, varscan2
- IGSF9 | c.1901G>A p.R634K (on ENST00000368094 / NM_001135050.2; = p.R618K on NM_020789.4) | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV100829649; called by muse, mutect2, varscan2
- KALRN | c.268T>A p.C90S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as COSV99566092; called by muse, mutect2, varscan2
- KAT6B | c.4570G>A p.D1524N | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs545973592, COSV99768640; called by muse, mutect2, varscan2
- KCNV1 | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99819279; called by muse, mutect2, varscan2
- KCTD3 | c.1631C>T p.S544F | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV99379543; called by muse, mutect2, varscan2
- KIAA1210 | c.2977C>T p.P993S | Missense Mutation (SNP) | VAF 35/46 reads (76%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.546); catalogued as COSV101274325; called by muse, mutect2, varscan2
- KIDINS220 | c.3926C>T p.S1309F | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.035); catalogued as rs781272996, COSV99876128; called by muse, mutect2, varscan2
- KIF1B | c.5011C>T p.P1671S (on ENST00000377086 / NM_001365952.1; = p.P1625S on NM_015074.3) | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99823818; called by muse, mutect2, varscan2
- KLB | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV99962356; called by muse, mutect2, varscan2
- KLHL6 | c.32C>T p.T11I | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as COSV100384878; called by muse, mutect2, varscan2
- KLKB1 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV99250237; called by muse, mutect2, varscan2
- KMT2C | c.7783C>T p.P2595S | Missense Mutation (SNP) | VAF 73/126 reads (58%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as COSV100074543; called by muse, mutect2, varscan2
- LIN28A | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs141345172, COSV54261260; called by muse, mutect2, varscan2
- LRP1B | c.4907A>C p.N1636T | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV101258502; called by muse, mutect2, varscan2
- MACF1 | c.11449C>T p.Q3817* (on ENST00000372915; = p.Q1750* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 26/67 reads (39%) | catalogued as COSV99245818; called by muse, mutect2, varscan2
- MACF1 | c.17926G>A p.D5976N (on ENST00000372915; = p.D4021N on NM_012090.5) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | catalogued as COSV99245819; called by muse, mutect2, varscan2
- MAGEA10 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 60/79 reads (76%) | SIFT tolerated (0.19); PolyPhen benign (0.082); catalogued as COSV99726820; called by muse, mutect2, varscan2
- MAGEA12 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 106/146 reads (73%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV100756987; called by muse, mutect2, varscan2
- MAGI2 | c.3757G>A p.E1253K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1240519716, COSV62648071, COSV62690145; called by muse, mutect2, varscan2
- MAGI2 | c.2064G>A p.W688* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV100835530; called by muse, mutect2, varscan2
- MAP2K3 | c.411G>A p.W137* (on ENST00000342679 / NM_145109.3; = p.W108* on NM_002756.4) | Nonsense Mutation (SNP) | VAF 9/70 reads (13%) | catalogued as COSV100384211, COSV57568309; called by muse, mutect2
- MAPK15 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as COSV100568015; called by muse, mutect2, varscan2
- MAST4 | c.3037C>A p.Q1013K (on ENST00000403625 / NM_001164664.2; = p.Q824K on NM_015183.3) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.615); catalogued as COSV99845068; called by muse, mutect2, varscan2
- METAP1D | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.159); catalogued as rs772966640, COSV59928967; called by mutect2, varscan2
- MGAT2 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100023594; called by muse, mutect2, varscan2
- MLXIP | c.2521A>G p.I841V | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV100038948; called by muse, mutect2, varscan2
- MMP13 | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.539); catalogued as COSV99506727; called by muse, mutect2, varscan2
- MUC16 | c.8717C>T p.S2906F | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as COSV67486209; called by muse, mutect2, varscan2
- MUC4 | c.12914C>T p.A4305V (on ENST00000463781 / NM_018406.7; = p.A69V on NM_004532.6) | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as COSV100205606; called by muse, varscan2
- MYH1 | c.4057G>A p.E1353K | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV56849158, COSV99876507; called by muse, mutect2, varscan2
- MYH1 | c.339G>A p.W113* | Nonsense Mutation (SNP) | VAF 68/134 reads (51%) | catalogued as COSV55451606; called by muse, mutect2, varscan2
- MYH2 | c.2602G>A p.E868K | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.052); catalogued as rs267604724, COSV55432215; called by muse, mutect2, varscan2
- MYH8 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV101238225; called by muse, mutect2, varscan2
- MYO9B | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101261740; called by muse, mutect2, varscan2
- MYOM2 | c.2137C>T p.H713Y | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs779315427, COSV100037990; called by muse, mutect2, varscan2
- NCKAP5 | c.4760A>T p.N1587I | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.406); catalogued as COSV100493526; called by muse, mutect2, varscan2
- NCOA3 | c.2453C>T p.S818F | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.798); catalogued as COSV100507896; called by muse, mutect2, varscan2
- NELL2 | c.1815G>T p.E605D | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV100420238; called by muse, mutect2, varscan2
- NFKBID | c.875C>T p.P292L (on ENST00000396901; = p.P444L on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.84); catalogued as rs200193671, COSV100573252; called by muse, mutect2, varscan2
- NFKBID | c.874C>T p.P292S (on ENST00000396901; = p.P444S on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as COSV61729645; called by muse, mutect2, varscan2
- NLRP12 | c.2902C>T p.P968S | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV100144678; called by muse, mutect2, varscan2
- NLRP2 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.811); catalogued as rs760197573, COSV99672478; called by muse, mutect2, varscan2
- NR1H4 | c.289G>A p.E97K (on ENST00000551379 / NM_001206993.2; = p.E87K on NM_005123.4) | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); catalogued as rs750165978, COSV99500914; called by muse, mutect2, varscan2
- NTM | c.209A>G p.N70S | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100869104; called by muse, mutect2, varscan2
- OBSL1 | c.3751C>T p.P1251S | Missense Mutation (SNP) | VAF 54/87 reads (62%) | SIFT tolerated (0.27); PolyPhen benign (0.113); catalogued as COSV99216236; called by muse, mutect2, varscan2
- OPRK1 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 47/79 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55569122; called by muse, mutect2, varscan2
- OR10P1 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100548198; called by muse, mutect2, varscan2
- OR13C8 | c.339G>A p.M113I | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100623048, COSV58611198, COSV58611995; called by muse, mutect2, varscan2
- OR13H1 | c.839T>C p.L280S | Missense Mutation (SNP) | VAF 40/55 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100088339; called by muse, mutect2, varscan2
- OR14J1 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 88/224 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1297774139, COSV101012820; called by muse, mutect2, varscan2
- OR1D2 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV58921245; called by muse, mutect2, varscan2
- OR1D5 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101643438; called by muse, mutect2, varscan2
- OR4K15 | c.647C>T p.T216I (on ENST00000305051; = p.T192I on NM_001005486.1) | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.33); catalogued as rs1036957849, COSV100521110; called by muse, mutect2, varscan2
- OR4K2 | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.047); catalogued as rs533563898, COSV100064631, COSV53848084; called by muse, mutect2, varscan2
- OR5AP2 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100266346; called by muse, mutect2, varscan2
- OR5T3 | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV100282875; called by muse, varscan2
- OTOGL | c.2857G>A p.D953N (on ENST00000547103; = p.D944N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200438973, COSV101509448; called by muse, mutect2, varscan2
- PANK3 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99496511; called by muse, mutect2, varscan2
- PAXBP1 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs576995361, COSV99269427; called by muse, mutect2, varscan2
- PBK | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.346); catalogued as COSV100107413; called by muse, mutect2, varscan2
- PCDH15 | c.488G>A p.G163D | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1314363353, COSV100224603, COSV57313979; called by muse, mutect2, varscan2
- PCDHA13 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 31/43 reads (72%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.932); catalogued as COSV99167732; called by muse, mutect2, varscan2
- PCSK4 | c.802G>A p.V268M | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99278762; called by muse, mutect2, varscan2
- PDYN | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.156); catalogued as COSV99453200; called by muse, mutect2, varscan2
- PEG3 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV99689738; called by muse, mutect2, varscan2
- PHLDB2 | c.2488-1G>T p.X830_splice (on ENST00000393925 / NM_001134439.2; = p.X787_splice on NM_145753.2) | Splice Site (SNP) | VAF 18/72 reads (25%) | catalogued as COSV101208600; called by muse, mutect2, varscan2
- PITPNM1 | c.584T>C p.V195A | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV100039441; called by muse, mutect2, varscan2
- PITPNM3 | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs768310521, COSV99338758; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLA2G4F | c.2209C>T p.P737S | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV101215281; called by muse, mutect2, varscan2
- PLAT | c.1452A>T p.R484S | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as COSV99535323; called by muse, mutect2, varscan2
- PLXNA2 | c.3035C>T p.S1012F | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as COSV100885664; called by muse, mutect2, varscan2
- PNMA3 | c.1177C>T p.R393* | Nonsense Mutation (SNP) | VAF 29/41 reads (71%) | catalogued as rs782671536, COSV64722184; called by muse, mutect2, varscan2
- PPARGC1A | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs368992605; called by muse, mutect2, varscan2
- PPP2R5A | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV99806824; called by muse, mutect2, varscan2
- PRKCB | c.1562C>T p.S521F | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100334749; called by muse, mutect2, varscan2
- PTGES2 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as rs368606962, COSV99476419; called by muse, mutect2, varscan2
- PTPRB | c.3649G>A p.E1217K | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.217); catalogued as COSV54254955; called by muse, mutect2, varscan2
- PTPRK | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV100951396; called by muse, mutect2, varscan2
- PTPRR | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51736511; called by muse, mutect2, varscan2
- RELN | c.5158del p.E1720Kfs*109 | Frame Shift Del (DEL) | VAF 15/61 reads (25%) | catalogued as COSV58998218; called by mutect2, pindel, varscan2
- RGS7 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755007339, COSV58530073, COSV58530443; called by muse, mutect2, varscan2
- RIC8A | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.481); catalogued as COSV100254880; called by muse, mutect2, varscan2
- RIOK1 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.379); catalogued as COSV99344872; called by muse, mutect2, varscan2
- RIOK2 | c.386G>A p.R129K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99300123; called by muse, mutect2, varscan2
- RIPK2 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); catalogued as COSV99610039; called by muse, mutect2, varscan2
- RNF112 | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as COSV101465423; called by muse, mutect2, varscan2
- RNF43 | c.2044C>T p.P682S | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.111); catalogued as rs1304658474, COSV68458823, COSV68460450; called by muse, mutect2, varscan2
- ROBO2 | c.3226C>A p.P1076T | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs776356404, COSV100168583; called by muse, mutect2, varscan2
- RTL1 | c.2857G>A p.D953N | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.159); catalogued as COSV66016542; called by muse, mutect2, varscan2
- RXFP2 | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV100034453; called by muse, mutect2, varscan2
- RYR2 | c.4531G>A p.V1511M | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1298609322, COSV100772032; called by muse, mutect2, varscan2
- SCN9A | c.3067G>A p.E1023K (on ENST00000303354; = p.E1012K on NM_002977.3) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV100313552; called by muse, mutect2, varscan2
- SCN9A | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100313561; called by muse, mutect2, varscan2
- SEMA4A | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs1424714812, COSV100740677; called by muse, mutect2
- SERPINA4 | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.131); catalogued as rs750919806, COSV100097352; called by muse, mutect2, varscan2
- SERPINB3 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.167); catalogued as COSV99380068; called by muse, mutect2, varscan2
- SHROOM3 | c.5111C>T p.P1704L | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV56042115; called by muse, mutect2, varscan2
- SIPA1L3 | c.673T>C p.F225L | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.831); catalogued as COSV99729732; called by muse, mutect2, varscan2
- SLAMF8 | c.614A>G p.N205S | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99223044; called by muse, mutect2, varscan2
- SLC17A4 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV100930640; called by muse, mutect2, varscan2
- SLC26A8 | c.1973A>C p.E658A | Missense Mutation (SNP) | VAF 87/179 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as COSV100839555; called by muse, mutect2, varscan2
- SLC26A9 | c.610A>C p.I204L | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs760200702, COSV100536581; called by muse, mutect2, varscan2
- SLC45A3 | c.304C>T p.L102F | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.116); catalogued as COSV100901274; called by muse, mutect2, varscan2
- SOWAHB | c.2338G>A p.E780K | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.494); catalogued as rs761250663, COSV100530754; called by muse, mutect2, varscan2
- SPDL1 | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV54670361; called by muse, mutect2, varscan2
- SPOCD1 | c.2459C>T p.A820V | Missense Mutation (SNP) | VAF 79/224 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV99930147; called by muse, mutect2, varscan2
- SPOCK3 | c.1267G>A p.G423R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.999); catalogued as rs1409400981, COSV100693521, COSV62724426; called by muse, mutect2, varscan2
- SPTA1 | c.5977G>A p.D1993N | Missense Mutation (SNP) | VAF 124/373 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.151); catalogued as COSV100935267; called by muse, mutect2
- SPTA1 | c.2221G>A p.D741N | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.151); catalogued as rs765936247, COSV63751924; called by muse, mutect2, varscan2
- SRCAP | c.7138C>T p.R2380W | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV52680434; called by muse, mutect2, varscan2
- SSH2 | c.3004C>T p.P1002S | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.012); catalogued as COSV99282600; called by muse, mutect2, varscan2
- STAG3 | c.2288C>T p.S763L | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.269); catalogued as COSV100426101; called by muse, mutect2, varscan2
- STK31 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100669730; called by muse, mutect2, varscan2
- STYXL2 | c.3040G>A p.E1014K | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV54811249; called by muse, mutect2, varscan2
- SVEP1 | c.7163C>T p.S2388F | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.622); catalogued as COSV52840949; called by muse, mutect2, varscan2
- SVOPL | c.631C>T p.P211S (on ENST00000419765; = p.P59S on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99939510; called by muse, mutect2, varscan2
- SYCP1 | c.2261C>T p.S754F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1400249491, COSV101051046; called by muse, mutect2, varscan2
- SYCP1 | c.2424G>A p.W808* | Nonsense Mutation (SNP) | VAF 15/56 reads (27%) | catalogued as COSV65699901; called by muse, mutect2, varscan2
- SYNE2 | c.10465C>T p.Q3489* | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | catalogued as COSV100648176; called by muse, mutect2, varscan2
- TACC2 | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV100553170; called by muse, mutect2, varscan2
- TAS2R13 | c.142C>T p.L48F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs1402985137, COSV66831910; called by muse, varscan2
- TBC1D9B | c.3266C>T p.P1089L (on ENST00000356834 / NM_198868.3; = p.P1072L on NM_015043.4) | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV100783585; called by muse, mutect2, varscan2
- TCF3 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV53649179; called by muse, mutect2, varscan2
- TCHHL1 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs759401679, COSV100916572; called by muse, mutect2, varscan2
- TENM3 | c.6193G>A p.D2065N | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.414); catalogued as COSV101305295; called by muse, mutect2, varscan2
- TENM4 | c.4213C>T p.H1405Y | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV53681953; called by muse, mutect2, varscan2
- TFAP2C | c.1015C>T p.L339F | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as COSV99571634; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1877C>T p.S626F | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.285); catalogued as COSV99305317; called by muse, mutect2, varscan2
- TGM2 | c.1455G>A p.M485I | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100821703; called by muse, mutect2
- THSD7B | c.2794G>A p.G932R | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99755128; called by muse, mutect2, varscan2
- TICRR | c.1238C>T p.S413F | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV51542028, COSV99177467; called by muse, mutect2, varscan2
- TLNRD1 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99146136; called by muse, mutect2, varscan2
- TMC5 | c.1149-1G>A p.X383_splice (on ENST00000396229 / NM_001105248.1; = p.X137_splice on NM_024780.5) | Splice Site (SNP) | VAF 16/59 reads (27%) | catalogued as COSV99572717; called by muse, mutect2, varscan2
- TMEM74 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV52463980, COSV99865783; called by muse, mutect2, varscan2
- TNS3 | c.2876C>T p.S959F | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs754925928, COSV100236042; called by muse, varscan2
- TNXB | c.8600C>T p.T2867I (on ENST00000647633; = p.T2620I on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.886); catalogued as COSV100926469; called by muse, mutect2, varscan2
- TRIM51 | c.1229G>A p.G410E | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99792979; called by muse, mutect2, varscan2
- TRIM55 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 93/181 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99397062; called by muse, mutect2, varscan2
- TRIM71 | c.2357C>T p.S786L | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as rs749936473, COSV67470505; called by muse, mutect2, varscan2
- TRIML1 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.83); PolyPhen benign (0.009); catalogued as rs553268136, COSV60195578, COSV60196750; called by muse, mutect2, varscan2
- TRIML2 | c.1081C>G p.L361V | Missense Mutation (SNP) | VAF 62/208 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100456217; called by muse, mutect2
- TRPV5 | c.1455G>A p.M485I | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.942); catalogued as COSV99520802; called by muse, mutect2, varscan2
- TSC22D1 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV101488140; called by muse, mutect2, varscan2
- TSHZ2 | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100296487; called by muse, mutect2, varscan2
- TTC27 | c.2045G>A p.R682Q | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.315); catalogued as rs147021005; called by muse, mutect2, varscan2
- TUBGCP6 | c.765G>A p.W255* | Nonsense Mutation (SNP) | VAF 19/46 reads (41%) | catalogued as COSV99352546; called by muse, mutect2, varscan2
- TYK2 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as rs150331673, COSV99315074; called by muse, mutect2, varscan2
- UGT2B4 | c.1415G>A p.G472E | Missense Mutation (SNP) | VAF 64/197 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100522547; called by muse, mutect2, varscan2
- UIMC1 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.351); catalogued as rs762592340, COSV101022194, COSV65895160; called by muse, mutect2, varscan2
- UPK1A | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.018); catalogued as COSV99721986; called by muse, mutect2, varscan2
- USP40 | c.2779C>T p.P927S | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99296845; called by muse, mutect2, varscan2
- VEZT | c.2198C>T p.P733L | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs1176829668, COSV99704138; called by muse, mutect2, varscan2
- VWA3B | c.3568A>T p.K1190* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as COSV101417839; called by muse, mutect2, varscan2
- WDR17 | c.1774C>T p.R592* | Nonsense Mutation (SNP) | VAF 21/55 reads (38%) | catalogued as rs556941855, COSV54567462; called by muse, mutect2, varscan2
- XYLT1 | c.2324G>A p.G775E | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54489121; called by muse, mutect2, varscan2
- ZAN | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 99/260 reads (38%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.895); catalogued as rs375614439; called by muse, mutect2, varscan2
- ZBTB1 | c.1765C>T p.Q589* | Nonsense Mutation (SNP) | VAF 27/66 reads (41%) | catalogued as COSV100704189; called by muse, mutect2, varscan2
- ZNF318 | c.2828T>G p.V943G | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV100546388; called by muse, mutect2, varscan2
- ZNF318 | c.2827G>A p.V943M | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.164); catalogued as rs1377159080, COSV100546389; called by muse, mutect2, varscan2
- ZNF442 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV99664456; called by muse, mutect2, varscan2
- ZNF530 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs144027172, COSV60531494; called by muse, mutect2, varscan2
- ZNF560 | c.398A>G p.N133S | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.208); catalogued as COSV100038844; called by muse, mutect2, varscan2
- ZNF71 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as COSV100046144; called by muse, mutect2, varscan2
- ZSCAN20 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100792690; called by muse, mutect2, varscan2
- FCGBP | c.3221C>A p.P1074H | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- NRIP1 | c.2854del p.H952Tfs*18 | Frame Shift Del (DEL) | VAF 28/80 reads (35%) | called by mutect2, varscan2
- SLC35B1 | c.618_621delinsT p.G207del (on ENST00000649906; = p.G170del on NM_005827.4) | In Frame Del (DEL) | VAF 22/87 reads (25%) | called by pindel, varscan2*
- TRAV19 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, varscan2
- TRAV8-4 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- AAAS | c.780C>T p.L260= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs997721955, COSV99267060; called by muse, mutect2, varscan2
- ACHE | c.987C>A p.S329= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV99574325; called by muse, mutect2, varscan2
- ACVR1B | c.966C>T p.I322= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs763203996, COSV57775230; called by muse, mutect2, varscan2
- ADAM20 | c.1965C>T p.N655= | Silent (SNP) | VAF 75/215 reads (35%) | catalogued as COSV99833515; called by muse, mutect2, varscan2
- ADGRE1 | c.1179C>T p.F393= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as COSV99165565; called by muse, mutect2, varscan2
- AHCY | c.694C>T p.L232= | Silent (SNP) | VAF 44/119 reads (37%) | catalogued as COSV54152479, COSV99464365; called by muse, mutect2, varscan2
- AKAP8 | c.952C>T p.L318= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as rs754858114, COSV99512053; called by muse, mutect2, varscan2
- AKAP8L | c.1512C>T p.T504= | Silent (SNP) | VAF 50/152 reads (33%) | catalogued as rs369447883; called by muse, mutect2, varscan2
- AKR1A1 | c.645C>T p.S215= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV100698772; called by muse, mutect2, varscan2
- ARHGEF10 | c.2496C>T p.F832= (on ENST00000398564; = p.F807= on NM_014629.4) | Silent (SNP) | VAF 31/95 reads (33%) | catalogued as COSV100035071; called by muse, mutect2, varscan2
- ARHGEF7 | c.2295G>A p.L765= (on ENST00000375741 / NM_001113511.2; = p.L744= on NM_145735.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as COSV99521888; called by muse, mutect2, varscan2
- C1QTNF7 | c.630G>A p.L210= | Silent (SNP) | VAF 39/136 reads (29%) | catalogued as COSV99765379; called by muse, mutect2, varscan2
- CACNA1D | c.924C>T p.I308= | Silent (SNP) | VAF 70/195 reads (36%) | catalogued as rs753132052, COSV55437490; called by muse, varscan2
- CAMK4 | c.255C>T p.I85= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as rs201866448, COSV56662707; called by muse, mutect2, varscan2
- CAMSAP3 | c.1479G>A p.K493= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV99351397; called by muse, mutect2, varscan2
- CAPN13 | c.1383G>A p.Q461= | Silent (SNP) | VAF 64/187 reads (34%) | catalogued as COSV99700614; called by muse, mutect2, varscan2
- CDC25B | c.1152C>T p.L384= (on ENST00000245960 / NM_021873.3; = p.L370= on NM_004358.4) | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV99848189; called by muse, mutect2, varscan2
- CHAMP1 | c.1869C>T p.N623= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as rs782577622, COSV100778842; called by muse, mutect2, varscan2
- CLTB | c.468C>T p.I156= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs760569600, COSV100125051; called by muse, varscan2
- CPNE9 | c.1560G>A p.E520= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as COSV99808394; called by muse, mutect2, varscan2
- CPT1C | c.1782C>T p.F594= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs376737655, COSV54918218, COSV99773566; called by muse, mutect2, varscan2
- CREB3L3 | c.939C>T p.S313= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV99314352; called by muse, mutect2, varscan2
- CSMD3 | c.1596T>A p.V532= (on ENST00000297405 / NM_001363185.1; = p.V428= on NM_052900.3) | Silent (SNP) | VAF 34/69 reads (49%) | catalogued as COSV99841491; called by muse, mutect2, varscan2
- CUX2 | c.3120C>T p.I1040= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as rs1405869296, COSV55629406; called by muse, mutect2, varscan2
- CYFIP2 | c.3000C>T p.F1000= (on ENST00000616178 / NM_001291722.2; = p.F975= on NM_014376.4) | Silent (SNP) | VAF 21/36 reads (58%) | catalogued as COSV100557463; called by muse, mutect2, varscan2
- CYP2F1 | c.210G>T p.L70= | Silent (SNP) | VAF 40/122 reads (33%) | catalogued as COSV100462846; called by muse, mutect2, varscan2
- DLEC1 | c.2025G>A p.K675= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as COSV100343017; called by muse, mutect2, varscan2
- DNAH17 | c.4816C>T p.L1606= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV101102943; called by muse, mutect2, varscan2
- DNAJC6 | c.2067C>T p.S689= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as COSV99675335; called by muse, mutect2, varscan2
- ELAVL3 | c.786C>T p.I262= | Silent (SNP) | VAF 129/353 reads (37%) | catalogued as rs367695200; called by muse, mutect2, varscan2
- EOMES | c.1662C>T p.P554= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as rs752005397, COSV55410722; called by muse, mutect2, varscan2
- ESAM | c.876C>T p.P292= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV99632008; called by muse, mutect2, varscan2
- FAM3B | c.147G>A p.E49= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as rs777458036, COSV100783758, COSV63612991; called by muse, mutect2, varscan2
- FCGBP | c.3222C>T p.P1074= | Silent (SNP) | VAF 40/128 reads (31%) | catalogued as rs201662593; called by muse, mutect2, varscan2
- FGFR4 | c.112C>T p.L38= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV99450492; called by muse, mutect2, varscan2
- FLNB | c.3255C>T p.I1085= | Silent (SNP) | VAF 48/152 reads (32%) | catalogued as rs779160545, COSV99914055; called by muse, mutect2, varscan2
- FOXN2 | c.306G>A p.Q102= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as rs1047987448, COSV100489345; called by muse, mutect2, varscan2
- FRG2 | c.498C>T p.V166= | Silent (SNP) | VAF 81/216 reads (38%) | called by muse, mutect2, varscan2
- FRY | c.6096C>T p.S2032= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs1337672991, COSV100969449, COSV66570498; called by muse, mutect2, varscan2
- FSCN2 | c.760C>T p.L254= | Silent (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2
- GDAP1L1 | c.1005G>A p.K335= | Silent (SNP) | VAF 61/151 reads (40%) | catalogued as COSV100697629; called by muse, mutect2, varscan2
- GIMAP2 | c.711G>A p.K237= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs751294485, COSV99785450; called by muse, mutect2, varscan2
- GIMAP2 | c.849G>A p.L283= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1162231570, COSV99785452; called by muse, mutect2, varscan2
- GLB1 | c.378C>T p.I126= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as COSV56566147; called by muse, mutect2, varscan2
- GON4L | c.2166C>T p.T722= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as rs774269714, COSV99675165; called by muse, mutect2, varscan2
- GON4L | c.1273T>C p.L425= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as COSV99675174; called by muse, mutect2, varscan2
- GPRC5C | c.243C>T p.N81= (on ENST00000652232; = p.N36= on NM_018653.4) | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as rs145119311; called by muse, mutect2, varscan2
- GRID1 | c.801C>T p.I267= | Silent (SNP) | VAF 34/58 reads (59%) | catalogued as COSV60017428; called by muse, mutect2, varscan2
- GRM7 | c.987C>T p.I329= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as rs373414573; called by muse, mutect2, varscan2
- GRXCR1 | c.42G>A p.R14= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as COSV101295728; called by muse, mutect2, varscan2
- GSDMC | c.1314C>T p.F438= | Silent (SNP) | VAF 42/86 reads (49%) | catalogued as COSV99416268; called by muse, mutect2, varscan2
- HEATR5B | c.4800T>C p.C1600= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV99249866; called by muse, mutect2, varscan2
- HEATR5B | c.1080C>T p.I360= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as rs767346833, COSV99249870; called by muse, mutect2, varscan2
- HECTD4 | c.5859C>T p.I1953= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV66397026; called by muse, mutect2
- HIVEP3 | c.7197G>A p.E2399= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99913371; called by muse, mutect2, varscan2
- HK3 | c.2322C>T p.F774= | Silent (SNP) | VAF 42/129 reads (33%) | catalogued as COSV99458983; called by muse, mutect2, varscan2
- HSPA4 | c.660G>A p.L220= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as COSV100507770; called by muse, mutect2, varscan2
- IL9R | c.1086C>T p.G362= | Silent (SNP) | VAF 36/80 reads (45%) | catalogued as COSV99730055; called by muse, mutect2, varscan2
- ITGB3 | c.771C>T p.V257= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as COSV71383787, COSV71384252; called by muse, varscan2
- KALRN | c.6762A>G p.Q2254= (on ENST00000360013 / NM_001024660.4; = p.Q557= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/118 reads (31%) | catalogued as COSV99362531; called by muse, mutect2, varscan2
- KCNV1 | c.372C>T p.V124= | Silent (SNP) | VAF 31/54 reads (57%) | catalogued as COSV99819283; called by muse, mutect2, varscan2
- KRT40 | c.123C>T p.S41= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as COSV100898875; called by muse, mutect2, varscan2
- KRT6B | c.1152C>T p.I384= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as COSV99360875; called by muse, mutect2, varscan2
- KRTAP27-1 | c.453C>T p.F151= | Silent (SNP) | VAF 67/168 reads (40%) | catalogued as rs781274963, COSV67000922; called by muse, mutect2, varscan2
- LENG8 | c.1650C>T p.I550= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as rs761941097, COSV58726992; called by muse, mutect2
- LPAR2 | c.39C>T p.I13= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as rs772311027, COSV52554218, COSV52558369; called by muse, mutect2, varscan2
- LRIG2 | c.543C>T p.T181= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100743549; called by muse, mutect2, varscan2
- LRRC4B | c.1287G>A p.Q429= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as rs1448104767, COSV100975992; called by muse, mutect2, varscan2
- LY6D | c.366C>T p.V122= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as COSV100009321; called by muse, mutect2, varscan2
- LY9 | c.447C>T p.F149= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs373033533, COSV54434619; called by muse, mutect2, varscan2
- MAPK8IP1 | c.801C>T p.I267= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV53796618; called by muse, mutect2, varscan2
- MERTK | c.1992C>T p.I664= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV99774988; called by muse, mutect2, varscan2
- MET | c.1902C>T p.F634= | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as rs772450441, COSV100577063; ClinVar: likely benign; called by muse, mutect2
- MGAM | c.3087C>T p.A1029= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as COSV72074619; called by muse, mutect2, varscan2
- MICALL1 | c.687C>T p.T229= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV99317458; called by muse, mutect2, varscan2
- MRM2 | c.495C>T p.L165= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as rs193099124, COSV99642744; called by muse, mutect2, varscan2
- MRPL21 | c.15C>T p.S5= | Silent (SNP) | VAF 70/151 reads (46%) | catalogued as COSV99662355; called by muse, mutect2, varscan2
- MUC16 | c.5199C>T p.S1733= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as rs533670609, COSV101200582; called by muse, mutect2, varscan2
- MXRA5 | c.6147C>T p.I2049= | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as COSV99478227; called by muse, mutect2
- MYH15 | c.858G>A p.V286= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV56316833; called by muse, mutect2, varscan2
- MYO5B | c.3081G>A p.L1027= | Silent (SNP) | VAF 35/114 reads (31%) | catalogued as COSV99545839; called by muse, mutect2, varscan2
- NAV2 | c.3630C>T p.N1210= (on ENST00000396087 / NM_001244963.2; = p.N1187= on NM_145117.5) | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV100217368; called by muse, mutect2, varscan2
- NELFE | c.828C>T p.L276= | Silent (SNP) | VAF 43/124 reads (35%) | catalogued as COSV64814174; called by muse, mutect2, varscan2
- NLRP5 | c.2011C>T p.L671= | Silent (SNP) | VAF 43/122 reads (35%) | catalogued as COSV66762692; called by muse, mutect2, varscan2
- NUP210 | c.3516C>T p.I1172= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV54415626; called by muse, mutect2, varscan2
- OBSCN | c.12369G>C p.T4123= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV52754779, COSV99482039; called by muse, mutect2, varscan2
- OPRK1 | c.729C>T p.I243= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as rs1413016291, COSV55575408; called by muse, mutect2, varscan2
- OR10G2 | c.144C>T p.L48= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as COSV101606965; called by muse, mutect2
- OR10P1 | c.666C>T p.I222= | Silent (SNP) | VAF 46/142 reads (32%) | catalogued as COSV59008415; called by muse, mutect2, varscan2
- OR10Z1 | c.306C>T p.F102= | Silent (SNP) | VAF 67/188 reads (36%) | catalogued as COSV100778936, COSV63524662; called by muse, mutect2, varscan2
- OR14I1 | c.468C>T p.V156= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV100700466, COSV100700468; called by muse, mutect2, varscan2
- OR1J2 | c.363C>T p.D121= | Silent (SNP) | VAF 26/39 reads (67%) | catalogued as COSV100093329; called by muse, mutect2, varscan2
- OR2AG2 | c.351C>T p.F117= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as COSV58456062; called by muse, mutect2, varscan2
- OR3A2 | c.744C>T p.S248= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as COSV101375067, COSV68695009; called by muse, mutect2, varscan2
- OR4B1 | c.147C>T p.I49= | Silent (SNP) | VAF 56/155 reads (36%) | catalogued as rs745651528, COSV100535657; called by muse, mutect2, varscan2
- OR4D5 | c.312C>T p.F104= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as COSV100190108; called by muse, mutect2, varscan2
- OR5L1 | c.750C>T p.V250= | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as COSV100450150; called by muse, mutect2, varscan2
- OR5T3 | c.378C>T p.L126= | Silent (SNP) | VAF 49/131 reads (37%) | catalogued as rs1183597874, COSV57382586; called by muse, varscan2
- OR8H3 | c.189C>T p.F63= | Silent (SNP) | VAF 70/214 reads (33%) | catalogued as COSV57907319; called by muse, mutect2, varscan2
- ORC2 | c.1167C>T p.F389= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as COSV99309652; called by muse, mutect2, varscan2
- OSMR | c.267G>A p.V89= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs866828886, COSV99953468; called by muse, mutect2, varscan2
- PCDHA1 | c.1395G>A p.K465= | Silent (SNP) | VAF 49/95 reads (52%) | catalogued as COSV100974410; called by muse, mutect2, varscan2
- PCSK9 | c.1443G>A p.E481= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as COSV100135413; called by muse, mutect2, varscan2
- PHKB | c.2994C>T p.I998= | Silent (SNP) | VAF 37/65 reads (57%) | catalogued as rs1420695588, COSV54517366, COSV54518228; called by muse, mutect2, varscan2
- PKD1 | c.921C>T p.F307= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as rs554071267, COSV51916542; called by muse, mutect2, varscan2
- PLXNA4 | c.2499C>T p.T833= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV100325859; called by muse, mutect2, varscan2
- PRAMEF15 | c.798C>T p.F266= | Silent (SNP) | VAF 76/364 reads (21%) | catalogued as COSV65999894; called by muse, mutect2, varscan2
- PRKAA2 | c.1308C>T p.Y436= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100982976; called by muse, mutect2, varscan2
- PROKR2 | c.225C>T p.I75= | Silent (SNP) | VAF 40/123 reads (33%) | catalogued as rs139296723; called by muse, mutect2, varscan2
- PRPF8 | c.5109C>T p.I1703= | Silent (SNP) | VAF 50/134 reads (37%) | catalogued as rs1328845406, COSV100517717; called by muse, varscan2
- PRR23B | c.753G>A p.P251= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as rs182603479; called by muse, mutect2, varscan2
- PRRT2 | c.798G>A p.R266= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as rs950332475, COSV99569394; called by muse, mutect2, varscan2
- PTPN22 | c.2244G>A p.R748= (on ENST00000359785 / NM_001193431.2; = p.R693= on NM_012411.5) | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV100703817; called by muse, mutect2, varscan2
- PTPRB | c.1860C>T p.S620= | Silent (SNP) | VAF 35/127 reads (28%) | catalogued as rs374912045, COSV99718282; called by muse, mutect2, varscan2
- PTPRF | c.4368C>T p.S1456= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV63443931; called by muse, mutect2
- SCN9A | c.1200G>A p.V400= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV100313556; called by muse, mutect2, varscan2
- SERPINA3 | c.81C>T p.S27= | Silent (SNP) | VAF 43/136 reads (32%) | catalogued as COSV101261763; called by muse, mutect2, varscan2
- SLC19A3 | c.903C>T p.I301= | Silent (SNP) | VAF 47/95 reads (49%) | catalogued as COSV99295988; called by muse, mutect2, varscan2
- SLC47A2 | c.48C>T p.C16= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100328157; called by muse, mutect2, varscan2
- SNTB2 | c.1452C>T p.P484= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV100293277; called by muse, mutect2, varscan2
- SPATA20 | c.1464C>T p.L488= (on ENST00000356488 / NM_001258372.1; = p.L504= on NM_022827.4) | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV99136353; called by muse, mutect2, varscan2
- SPATA7 | c.492C>T p.S164= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as rs1043718661, COSV99248210; called by muse, mutect2, varscan2
- SPRYD3 | c.334T>C p.L112= | Silent (SNP) | VAF 43/129 reads (33%) | catalogued as rs372974354; called by muse, mutect2, varscan2
- SRL | c.966C>T p.I322= | Silent (SNP) | VAF 58/184 reads (32%) | catalogued as rs756763066, COSV68424642; called by muse, mutect2, varscan2
- SSR4 | c.198C>T p.L66= | Silent (SNP) | VAF 30/36 reads (83%) | catalogued as COSV99381544; called by muse, mutect2, varscan2
- STYXL2 | c.3039G>A p.R1013= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV99609581; called by muse, mutect2, varscan2
- SVEP1 | c.7662C>T p.I2554= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV99928585, COSV99929452; called by muse, mutect2, varscan2
- SYMPK | c.648C>T p.I216= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs1185447230, COSV99841915; called by muse, mutect2, varscan2
- TARS1 | c.1527C>T p.I509= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs376335480, COSV54308203; called by muse, mutect2, varscan2
- TBC1D28 | c.57C>T p.I19= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV61507751; called by muse, mutect2, varscan2
- TMC3 | c.2418C>T p.L806= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV100845962; called by muse, mutect2, varscan2
- TMEM132E | c.1059C>T p.P353= (on ENST00000321639; = p.P443= on NM_001304438.2) | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV100396606, COSV58696558; called by muse, mutect2, varscan2
- TMEM45A | c.799C>A p.R267= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV100058538; called by muse, mutect2, varscan2
- TMPRSS13 | c.1032C>T p.H344= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as COSV101471478; called by muse, mutect2, varscan2
- TNS3 | c.555C>T p.L185= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs746830919, COSV100236044, COSV100236789; called by muse, mutect2, varscan2
- TNS4 | c.1629C>T p.I543= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as COSV99563999; called by muse, mutect2, varscan2
- TNXB | c.8601C>T p.T2867= (on ENST00000647633; = p.T2620= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 49/169 reads (29%) | catalogued as COSV100926468; called by muse, mutect2, varscan2
- TOMM34 | c.465G>A p.Q155= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as COSV100861918; called by muse, mutect2, varscan2
- TPO | c.258G>A p.V86= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV100221719; called by muse, varscan2
- TPP1 | c.123G>A p.A41= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as rs747260298, COSV100197614; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TRIM61 | c.189G>A p.R63= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as COSV61418963; called by muse, mutect2, varscan2
- TSHZ2 | c.825G>A p.L275= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV100296486; called by muse, mutect2, varscan2
- TTN | c.65091G>A p.R21697= (on ENST00000591111; = p.R14273= on NM_003319.4) | Silent (SNP) | VAF 51/100 reads (51%) | catalogued as COSV100622084; called by muse, mutect2, varscan2
- TTN | c.59520G>A p.G19840= (on ENST00000591111; = p.G12416= on NM_003319.4) | Silent (SNP) | VAF 67/120 reads (56%) | catalogued as rs747850027, COSV60171301; ClinVar: likely benign; called by muse, mutect2, varscan2
- UNC79 | c.7575C>T p.A2525= (on ENST00000393151 / NM_001346218.2; = p.A2348= on NM_020818.5) | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as COSV56399811; called by muse, mutect2, varscan2
- UTRN | c.4884C>T p.V1628= | Silent (SNP) | VAF 64/96 reads (67%) | catalogued as COSV100840136; called by muse, mutect2, varscan2
- VWC2L | c.360G>A p.G120= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs267599196, COSV56966796; called by muse, mutect2, varscan2
- WASHC2A | c.4002C>T p.P1334= | Silent (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- WFIKKN2 | c.573C>T p.T191= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV100259986; called by muse, mutect2, varscan2
- WRN | c.3057C>T p.S1019= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV53306799; called by muse, mutect2, varscan2
- WSCD2 | c.150G>A p.A50= | Silent (SNP) | VAF 55/183 reads (30%) | catalogued as rs367680277; called by muse, mutect2, varscan2
- ZBTB16 | c.685C>T p.L229= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs751396403, COSV100251833; called by muse, mutect2, varscan2
- ZNF425 | c.1977C>T p.V659= | Silent (SNP) | VAF 122/229 reads (53%) | catalogued as COSV100955546; called by muse, mutect2, varscan2
- ZNF808 | c.606C>T p.I202= | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as COSV100708012; called by muse, mutect2, varscan2
- ATG16L1 | c.954+1033C>T | Intron (SNP) | VAF 102/220 reads (46%) | catalogued as COSV61464077; called by muse, mutect2, varscan2
- CLCA3P | n.166C>T | RNA (SNP) | VAF 6/27 reads (22%) | catalogued as rs745413801; called by muse, mutect2, varscan2
- CSMD3 | c.178+59905G>A | Intron (SNP) | VAF 45/164 reads (27%) | catalogued as COSV52258677, COSV99841494; called by muse, mutect2, varscan2
- DCHS2 | n.2919G>A | RNA (SNP) | VAF 6/29 reads (21%) | catalogued as rs1247277130, COSV100252556; called by muse, mutect2, varscan2
- DRP2 | c.*2G>A | 3'UTR (SNP) | VAF 82/117 reads (70%) | catalogued as rs886221681, COSV101235249; called by muse, mutect2, varscan2
- DST | c.4296+4566A>G | Intron (SNP) | VAF 102/185 reads (55%) | catalogued as COSV99758396; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152445813 G>A | 3'Flank (SNP) | VAF 36/139 reads (26%) | called by muse, mutect2, varscan2
- NACA | c.71-3203C>T | Intron (SNP) | VAF 36/118 reads (31%) | catalogued as COSV63269752; called by muse, varscan2
- WNT3A | c.*786C>A | 3'UTR (SNP) | VAF 48/134 reads (36%) | catalogued as COSV99469884; called by muse, mutect2, varscan2
